Surgical pathology report (de-identified scan), TCGA case TCGA-34-5231, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-34-5231-01A (Primary Tumor).

FINAL DIAGNOSIS:

Summary Statement

The tumor is a 2.5 cm invasive moderately differentiated squamous cell carcinoma of the upper lobe of the right lung. A focus of perineural invasion is present. No pleural or angiolymphatic invasion is seen and all eighteen lymph nodes examined are free of tumor. All resection margins are free of tumor. There is also emphysematous change and respiratory bronchiolitis-associated interstitial lung disease. Report of microscopic finding of the rib will be issued an addendum following decalcification of the specimen. The pathologic stage of the tumor is T1N0mx.

PART 1: RIB, 5TH, RESECTION –

REPORT OF THE RIB WILL BE ISSUED IN AN ADDENDUM FOLLOWING DECALCIFICATION OF THE SPECIMEN.

PART 2: LYMPH NODE, ANTERIOR SEGMENT, LEVEL 11, SIDE NOT STATED, BIOPSY – TWO ANTHRACOTIC LYMPH NODES FREE OF TUMOR.

PART 3: LUNG, RIGHT UPPER LOBE, SLEEVE LOBECTOMY –

- A. INVASIVE MODERATELY DIFFERENTIATED SQUAMOUS CELL CARCINOMA (2.5 CM).
- B. A FOCUS OF PERINEURAL INVASION IS PRESENT.
- C. NO ANGIOLYMPHATIC INVASION SEEN.
- D. VISCERAL AND PARIETAL PLEURA FREE OF TUMOR.
- E. ALL RESECTION MARGINS ARE FREE OF TUMOR.
- F. APICAL FIBROSIS WITH FIBROUS ADHESION BETWEEN VISCERAL AND PARIETAL PLEURA.
- G. FIFTEEN ANTHRACOTIC PERIBRONCHIAL LYMPH NODES FREE OF TUMOR.
- H. EMPHYSEMATOUS CHANGE.
- I. RESPIRATORY BRONCHIOLITIS – ASSOCIATED INTERSTITIAL LUNG DISEASE.
- J. PATHOLOGIC STAGE T1N0MX.

PART 4: LYMPH NODE, LEVEL 10, SIDE NOT STATED, BIOPSY – ONE ANTHRACOTIC LYMPH NODE FREE OF TUMOR.

Addendum

The section of the rib (part 1) is free of tumor.

Source: NCI Genomic Data Commons file aafbb3ac-9f0f-4810-9843-f405fc727a6a (TCGA-34-5231.F86F0624-EDE3-4128-80C7-35D5F1D65FC4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).